CCDI case PBCMKT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a74b71ab-efa1-4aca-aedc-d679bebf1330

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal carcinoma, NOS: ICD-O-3 morphology code: 9070/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 2.6 years (934 days).

Biospecimens (3 samples)
- Sample 0DVCDW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCFK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVCFV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
